Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0GM, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0GM-TTM1-A (Metastatic).

[page 1 of 18]
Name:
DOB :
Rm #:

Doctor:
Unit #:
Acct #:

Date Collected: +20
Date Received : +20

Spec #:

PHYSICIAN COPIES:

DIAGNOSIS:

ADDENDUM REPORT

ADDENDUM COMMENT:

Immunoperoxidase stain directed against EGFR shows 3 to 4+ positivity in virtually all of the tumor cells.

DIAGNOSIS:

1. CARINAL LYMPH NODE:
METASTATIC ADENOCARCINOMA.
2. SUBCARINAL LYMPH NODE:
METASTATIC ADENOCARCINOMA.
3. RIGHT UPPER LYMPH NODE, 2R:
METASTATIC ADENOCARCINOMA.
4. RIGHT LOWER LYMPH NODE, 4R:
TWO BENIGN LYMPH NODES.
5. RIGHT MAINSTEM LYMPH NODE:
BENIGN LYMPH NODE.
6. CARINAL LYMPH NODES:
METASTATIC ADENOCARCINOMA IN 2/6 LYMPH NODES.

DEPARTMENT OF PATHOLOGY

[page 2 of 18]
Name : [REDACTED]
Unit #: [REDACTED] (cont)

Date: [REDACTED] +20 Spec #: [REDACTED] (continued)

DIAGNOSIS:

7. SUBCARINAL LYMPH NODES:

METASTATIC ADENOCARCINOMA IN 3/3 LYMPH NODES.

8. LEFT MAINSTEM LYMPH NODES:

METASTATIC ADENOCARCINOMA IN 2/3 LYMPH NODES.

SPECIMEN:

1. Carinal lymph node, for frozen section.
2. Subcarinal lymph node, for frozen section.
3. Right upper 2R.
4. Right lower 4R.
5. Right mainstem.
6. Carinal lymph node.
7. Subcarinal lymph node.
8. Left mainstem.

CLINICAL HISTORY/DIAGNOSES:

Left lung tumor.

FROZEN SECTION DIAGNOSIS:

Frozen section and touch preparation, specimen #1, carinal lymph node:

Metastatic non-small cell carcinoma. [REDACTED]

Frozen section, specimen #2, subcarinal lymph node:

Metastatic non-small cell carcinoma. [REDACTED]

GROSS DESCRIPTION:

Received are eight specimens labeled [REDACTED]

1. Received fresh for intraoperative consultation labeled "carinal lymph node" is a 0.5-cm pink, irregular soft tissue. A touch preparation is made. The tissue is submitted in its entirety, following frozen section

DEPARTMENT OF PATHOLOGY

[page 3 of 18]
Name :
Unit #:

(cont)

Date: +20

Spec #:

(continued)

GROSS DESCRIPTION:

analysis, as (1).

2. Received fresh for intraoperative consultation labeled "subcarinal lymph node" is a 1-cm in greatest dimension, pink, irregular soft tissue. A touch preparation is made. The specimen is submitted in its entirety following frozen section analysis as (2).

3. In formalin labeled "Rt. upper 2R" is a 0.7 x 0.3 x 0.3 cm pink, irregular soft tissue, submitted in toto as (3).

4. In formalin labeled "Rt. lower 4R" are two anthracotic, disrupted soft tissues up to 0.7 x 0.3 x 0.2 cm, submitted in toto as (4).

5. In formalin labeled "Rt. mainstem" is a 0.9 x 0.3 x 0.3 cm yellow to anthracotic soft tissue, submitted in toto as (5).

6. In formalin labeled "carinal lymph node" are five pink to anthracotic, irregular soft tissues up to 0.7 cm, submitted in toto as (6).

7. In formalin labeled "subcarinal lymph node" are four pink to anthracotic, irregular soft tissues up to 0.9 x 0.4 x 0.3 cm, submitted in toto as (7).

8. In formalin labeled "left mainstem" are three pink, irregular soft tissues up to 0.6 x 0.3 x 0.2 cm, submitted in toto as (8).

MICROSCOPIC:

Microscopic examination performed and supports the pathologic diagnosis.

DEPARTMENT OF PATHOLOGY

[page 4 of 18]
Name: [REDACTED]

DOB : [REDACTED]

Rm #: [REDACTED]

Doctor: [REDACTED]

Unit #: [REDACTED]

Acct #: [REDACTED]

Date Collected: [REDACTED]

+0

Date Received : [REDACTED]

+0

Spec #: [REDACTED]

PHYSICIAN COPIES:

DIAGNOSIS:

LUNG, LEFT, NEEDLE CORE BIOPSY:

MODERATELY TO POORLY-DIFFERENTIATED NON SMALL CELL CARCINOMA WITH
FEATURES SUGGESTIVE OF BRONCHOALVEOLAR CARCINOMA.

SPECIMEN:

Left lung needle core biopsy.

CLINICAL HISTORY/DIAGNOSES:

Mass, left lung.

GROSS DESCRIPTION:

Received in formalin labeled "[REDACTED]" are three gray cylindrical
soft tissues up to 0.6 x 0.1 x 0.1 cm, in toto.

Dictated By: [REDACTED]

Transcribed By: [REDACTED]

MICROSCOPIC:

Represented are needle biopsies of pulmonary tissue showing fibrosis and
focal neoplastic epithelial-appearing proliferation. The epithelial
proliferative process consists of strips and clusters of polygonal to
somewhat cuboidal epithelial cells having moderate quantities of
eosinophilic granular focally vacuolated cytoplasm and hyperchromatic
rounded to lobulated nuclei without visible nucleoli. A battery of
immunoperoxidase stains is performed demonstrating the
neoplastic-appearing cells to be positive on immunoperoxidase stains for
CEA, EMA, TTF1, LMW keratin and CK7. There is minimal positivity on the
immunoperoxidase stain for high-molecular weight keratin.
Neoplastic-appearing cells are negative on immunostains for CK20. The
lesion is compatible with poorly-differentiated adenocarcinoma of

DEPARTMENT OF PATHOLOGY

[page 5 of 18]
[REDACTED]

Name : [REDACTED]
Unit #: [REDACTED] (cont)

Date: [REDACTED] +0 Spec #: [REDACTED] (continued)

MICROSCOPIC:

pulmonary origin and has a pattern suggestive of bronchoalveolar carcinoma. Clinical correlation is recommended.

Transcribed By: [REDACTED]

[REDACTED]

☐ OK TO FILE ☐ PULL CHART ☐ PATIENT NOTIFIED BY ☐
☐ CALL PATIENT ☐ FINDINGS NORMAL ☐ FINDINGS ABNORMAL

DEPARTMENT OF PATHOLOGY

[page 6 of 18]
+1346

RUN DATE:
RUN TIME:

PAGE 1

Name:
Acct#:
Unit#:

Age/
DOB:

Attend D
LOC:

+1329

Specimen:

Collected:
Received:

Status: COMP
Ord Prov:

Ordered: MISC SEND OUT

Comments: SOMISC = EGFR TO / PARAFFIN BLOCK 7 SENT
AMBIENT

EGFR TESTING TO INCLUDE EXON 19, EXON 21, AND 790 MUTATIONS.

BLOCK COLLECTED +20

Test	Result	Flag	Reference	Perf Site
MISC SEND OUT	MISC SEND OUT			
FINAL RESULT 1				

EGFR MUTATION ANALYSIS

BODY SITE: SUBCARINAL LYMPH NODE

ETHNICITY:

CLINICAL DATA: NSCLC, FAVOR ADENOCARCINOMA

RESULTS: POSITIVE FOR THE E746_A750del5 MUTATION IN EXON 19.

INTERPRETATION: THE E746_A750del5 MUTATION ELIMINATES THE LREA MOTIF IN THE KINASE DOMAIN. DELETION OF THIS MOTIF IS REPORTED TO CORRELATE WITH RESPONSIVENESS TO EGFR TYROSINE KINASE INHIBITOR THERAPIES IN PATIENTS WITH NON-SMALL-CELL LUNG CANCER.

COMMENT: MUTATIONS IN THE TYROSINE KINASE DOMAIN OF THE EPIDERMAL GROWTH FACTOR RECEPTOR (EGFR) GENE ARE REPORTED TO BE ASSOCIATED WITH DIFFERENTIAL RESPONSIVENESS/RESISTANCE TO TARGETED THERAPEUTICS FOR NON-SMALL-CELL LUNG CANCER (NSCLC). THIS ASSAY ANALYZES EXONS 18-21 OF THE EGFR TYROSINE KINASE DOMAIN; BASED ON THE CURRENT LITERATURE, THE VAST MAJORITY OF MUTATIONS ARE EXPECTED TO OCCUR IN THESE EXONS. THE ANALYTICAL SENSITIVITY OF THE ASSAY IS 10-20%, THUS MUTATIONS PRESENT IN A LOW PERCENTAGE OF CELLS MAY NOT BE DETECTED.

LEGEND: H=above normal; L=below normal; #=exceeds delta check limit; *exceeds critical value
** CONTINUED ON NEXT PAGE **

[page 7 of 18]
Facility: .

Patient Name:
Unit Number:
Date of Birth:
Referring Dr.:
Rendering Dr.:

Procedure(s):
Accession #(s):
Date of exam:

-6

Report

CT OF THE THORAX WITH AND WITHOUT CONTRAST

HISTORY: Cough with left lung nodule

COMPARISON: None

TECHNIQUE: Initial 5 mm collimated images were obtained through a left lower lobe pulmonary nodule. Following this, nonionic intravenous contrast was administered with additional scans obtained. A final set of reconstructed 3 mm collimated images were also obtained.

FINDINGS: Within the left lower lobe near the major fissure there is a 1.9 x 1.4 cm enhancing pulmonary mass lesion (series 5, image #29). The remainder of the lung parenchyma reveals some scattered ground glass opacities and interstitial densities with no other pulmonary mass lesions or confluent areas of air space consolidation. There is minimal basilar scarring. There are no confluent areas of air space consolidation.

There are no pleural or pericardial effusions. There is no pneumothorax.

There are several mildly enlarged left hilar lymph nodes, the largest of which measures 1.4 x 1.0 cm (series 5, image #25). There is also right paratracheal and precarinal lymph adenopathy with the largest lymph node measuring 1.8 x 1.4 cm (series 5, image #15). There are nonenlarged prevascular and subcarinal lymph nodes. There are a few 7 mm superior

[page 8 of 18]
[REDACTED]

mediastinal lymph nodes. There is no axillary, supraclavicular, or retrocrural lymph adenopathy.

There are no central endobronchial lesions.

There are no filling defects within the central pulmonary arteries. The thoracic aorta exhibits no evidence of aneurysmal dilatation. The heart is not enlarged.

Imaging of the upper abdomen reveals a 2.3 x 1.4 cm early enhancing lesion within the right lobe of the liver (series 5, image #42). There are no adrenal gland masses. Imaging of the bones is unremarkable.

IMPRESSION:

1) There is a 1.9 x 1.4 cm enhancing left lower lobe pulmonary mass lesion with left hilar and mild mediastinal lymph adenopathy. This is concerning for primary neoplasm. Fine needle aspiration is recommended for further evaluation.

2) There is a 2.3 x 1.4 cm early enhancing lesion within the right lobe of the liver. The differential diagnosis includes a benign entity such as an atypical hemangioma, FNH and hepatic adenoma however hypervascular metastasis is a consideration as well. Recommend MRI imaging of the abdomen after the lung mass has been characterized.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 9 of 18]
[REDACTED]				
PATIENT	SEX	DOB	AGE	EXAM DATE
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED] +9
ORDERING PROVIDER	LOCATION	UNIT NUMBER	ACCT NUMBER	
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	

CC:

EXAM(S)

TUMOR IMAGING TORSO PET SCAN

WHOLE BODY PET-CT SCAN

HISTORY: Staging of left non-small cell lung carcinoma.

COMPARISON: CT chest [REDACTED] -6

PROCEDURE: A whole body PET scan was performed of the neck, chest, abdomen, and pelvis following the administration of FDG-18 17.2 mCi. A corresponding CT without IV contrast was performed for attenuation correction and fusion correlation purposes only. The PET and CT images were fused. Multiplanar reformatted images were created and viewed on the Vitrea workstation.

FINDINGS:

There is intense focal abnormal activity in the left lower lobe corresponding to a peripheral lung mass measuring 2 cm diameter. Maximum SUV of this mass is 6. There is also multifocal increased FDG activity in the left hilum corresponding to enlarged lymph nodes, and focal intense FDG activity corresponding to an enlarged 2 cm right tracheobronchial angle lymph node.

A small focus of FDG activity with maximum SUV of 3.8 in the right anterior neck near the thyroid isthmus and strap muscles is without CT correlate, and is of uncertain significance.

Normal heterogeneous background FDG activity throughout the liver. No focal increased activity corresponding to the hypervascular right liver lobe mass noted on the CT chest.

Unenhanced CT images demonstrate a 1.2 cm hypodense nodule in the right lobe of the thyroid gland without increased FDG activity. There is also a left ovarian cyst measuring 3.3 cm diameter without increased FDG activity.

IMPRESSION:

1. Malignant left lower lobe mass with abnormal FDG activity in several metastatic left hilar lymph nodes and a right

[page 10 of 18]
[REDACTED]				
PATIENT	SEX	DOB	AGE	EXAM DATE
[REDACTED]				+9
ORDERING PROVIDER	LOCATION		UNIT NUMBER	ACCT NUMBER
[REDACTED]				

CC:

EXAM(S)

TUMOR IMAGING TORSO PET SCAN

tracheobronchial angle lymph node in the mediastinum.

2. The hypervascular mass in the right liver lobe demonstrates normal FDG activity, and probably represents focal nodular hyperplasia or an hemangioma.

3. Low-density nodule in the right thyroid lobe measuring 1.3 cm.

4. Left ovarian cyst.

[REDACTED]

[REDACTED]

[page 11 of 18]
RADIOLOGY REPORT

Patient Information

Age/Sex: [REDACTED]

Birth Date: [REDACTED]

Signs & Symptoms: re-staging NSCLC due to uncontrolled pain

History: Malignant neoplasm of bronchus and lung, unspecified site

Order Information

Exam(s): **PET TUMOR IMAGING TORSO**

Exam Date: [REDACTED]

Ord Provider: [REDACTED]

+2701

Accession # [REDACTED]

Final

PET TUMOR IMAGING TORSO

+0

~+1239

~+2111

HISTORY: Patient diagnosed with lung cancer in [REDACTED] and is status post resection, chemotherapy and radiation therapy. The patient had CyberKnife for brain metastases in [REDACTED] and [REDACTED]. The patient also had brain surgery in [REDACTED]. Today's PET CT is ordered to restage disease.

~+2477

ADDITIONAL HISTORY: Kidney stone resection in [REDACTED]

~+2446

TECHNIQUE: After IV injection of F-18 FDG, whole body PET imaging was obtained from the cranial vertex to the proximal thighs. A non-attenuation corrected reconstruction was performed on this data set. Unenhanced CT images were then acquired on the PET/CT scanner and attenuation corrected reconstruction performed on the PET data. The PET and CT images were then transferred to an independent work station where image fusion, multiplanar reformatting, volume MIP and SUV calculations were performed.

CTDIvol: 14 mGy

DLP: 1447 mGy-cm

Dose: 16.5 Millicuries

Uptake delay vertex to thighs: 64 minutes

Serum glucose at time of injection: 107 mg/dl

Injection site: Right hand

COMPARISON: PET CT [REDACTED] +2442

FINDINGS:

[page 12 of 18]
PET FINDINGS:

Brain: Prior treated and resected metastatic lesions are better evaluated with brain MRI.

Head and neck: No hypermetabolic masses or hypermetabolic lymphadenopathy. Right hemithyroidectomy.

Chest: No hypermetabolic masses or hypermetabolic lymphadenopathy. Stable left subclavian Port-A-Cath with its tip near the cavoatrial junction. Paramediastinal and left hilar airspace disease, unchanged likely secondary to prior treatment.

Abdomen and pelvis: No hypermetabolic masses or hypermetabolic lymphadenopathy. No adrenal gland mass. No hydronephrosis.

Bones/soft tissues: No hypermetabolic bone lesion.

IMPRESSION:

1. Negative examination for hypermetabolic metastatic disease. No interval change.
2. Prior treated and resected brain metastases are better evaluated with brain MRI.

[page 13 of 18]
RADIOLOGY REPORT

MRN: [REDACTED]

Visit #: [REDACTED]

HAR: [REDACTED]

Patient Information

Age/Sex: [REDACTED]

Birth Date: [REDACTED]

Signs & Symptoms: 3 month follow up

History: Neoplasm of unspecified nature of brain

Order Information

Exam(s): **MR BRAIN W/WO CONTRAST** [REDACTED]

Accession #: [REDACTED]

Exam Date: [REDACTED] +2757

Ord Provider: [REDACTED]

Final

EXAMINATION:

MRI Brain without IV contrast

MRI Brain with IV contrast

HISTORY: Three-month followup. Lung cancer, status post resection of brain metastasis.
+2168, +2582 and +2658

COMPARISON: Brain MRIs from [REDACTED] and [REDACTED]

TECHNIQUE: Multi-planar, multi-sequence brain MRI was performed before and after IV gadolinium.

CONTRAST: 12 mL of IV MultiHance gadolinium.

FINDINGS:

Brain volume: Normal.

Sagittal midline structures: Normal.

Ventricles: Normal.

Acute ischemic changes: None.

Hemorrhage: None.

Masses / edema: Surgical cavity in the left posterior cerebellum is unchanged. There is no new vasogenic edema or mass effect.

[page 14 of 18]
[REDACTED]

Enhancement: Thin linear enhancement along the posterior margin of the surgical cavity in the left posterior fossa, and 2 thin linear areas of enhancement coursing through the operative cavity are unchanged. No nodular or new enhancement.

Gray-white: Negative.

White matter lesions: Normal.

Vessels: Normal.

Extra-axial: None.

Calvarium / scalp: Left occipital craniotomy.

Skull base: Negative.

Visualized sinuses / orbits: Negative.

Visualized upper neck: Negative.

IMPRESSION:

1. Postoperative changes from resection of a left cerebellar metastasis without evidence of residual or recurrent tumor.
2. No evidence of new intracranial metastases, infarct or hemorrhage.
- [REDACTED]
-
- [REDACTED]

[page 15 of 18]
PET IMAGING OF

RADIOLOGY REPORT

MRN: [REDACTED]

Patient Information

Age/Sex: [REDACTED]

Birth Date: [REDACTED]

Signs & Symptoms:

History: Cancer of overlapping sites of left lung (HC code)

Order Information

Exam(s): PET TUMOR IMAGING TORSO [REDACTED]

Accession #: [REDACTED]

Exam Date: [REDACTED] +4107

Ord Provide: [REDACTED]

Final

PET TUMOR IMAGING TORSO

+0

HISTORY: Lung cancer diagnosed [REDACTED] treated with surgery and chemoradiation. CyberKnife therapy for brain metastasis [REDACTED] Brain metastasis resection [REDACTED] Continued therapy. PET CT requested for restaging. ~+1239, ~+2111 ~+2477

TECHNIQUE: After IV injection of F-18 FDG, whole body PET imaging was obtained from the cranial vertex to the proximal thighs. A non-attenuation corrected reconstruction was performed on this data set. Unenhanced CT images were then acquired on the PET/CT scanner and attenuation corrected reconstruction performed on the PET data. The PET and CT images were then transferred to an independent work station where image fusion, multiplanar reformatting, volume MIP and SUV calculations were performed.

One of the following dose optimization techniques was utilized in the performance of this exam: automated exposure control; adjustment of the mA and/or kV according to patient size; or use of iterative reconstruction technique. Specific details can be referenced in the facility's radiology CT exam operational policy.

Dose: 15.8 Millicuries radiolabeled FDG
Uptake delay vertex to thighs: 60 minutes
Serum glucose at time of injection: 126 mg/dl
Injection site: Right hand
CTDIvol: 10 mGy
DLP: 983 mGy-cm

COMPARISON: [REDACTED] +3690

FINDINGS:

[page 16 of 18]
PET FINDINGS:

Brain: Negative.

Head and neck: Negative. Symmetric palatine tonsil uptake considered to be physiologic or inflammatory. Laryngeal uptake considered to be physiologic.

Chest: Negative. There is post radiation fibrosis in the left lung which is not significantly FDG avid, SUV max 2.8 compared to background blood pool activity of 2.6. Cavitary component seen on the prior is no longer present. There is no new pulmonary nodularity. Scarring or fibrosis in the right upper lobe medially is not FDG avid. There is warm uptake within a normal size and normal morphology right axillary lymph node which is significantly less than mediastinal blood pool activity with SUV max 2.0.

Abdomen and pelvis: There is physiologic bowel and GU system activity. A 1.6 cm right posterior segment liver lesion on series 2 image 136 remain stable in size and there is not FDG avid. Liver has its usual heterogeneous activity. There is hypermetabolism within nodules in the gluteal fat bilaterally measuring up to 1.4 x 2.0 cm on the right with SUV max 5.5, previously 2.3 x 2.4 cm with SUV 3.9. These remain most consistent with sites of medication injection and probable associated noncalcified noncalcified granulomatous or other inflammatory reaction. There are foci of gas within one of the sites of nodularity in the left related to recent injection.

Bones: Negative.

ADDITIONAL CT FINDINGS:

None significant. Streak artifact from dental amalgam. Left suboccipital craniotomy changes, mild degenerative changes in the spine, mild vascular calcifications. 3 mm nonobstructive renal stone. Previous right hemithyroidectomy.

IMPRESSION:

1. There is no evidence of FDG avid locally recurrent or metastatic disease.
2. Mild warm uptake within left lung post radiation fibrosis.
3. Hypermetabolic gluteal fat nodules consistent with noncalcified granulomatous or other inflammatory reaction at the sites of medication injection.

Report E-Signed By: [REDACTED]

[REDACTED]

[REDACTED]

[page 17 of 18]
RADIOLOGY REPORT

Patient Information

Age/Sex: [REDACTED]
Birth Date: [REDACTED]

Signs & Symptoms:
History: Brain metastasis (HC code)
Malignant
neoplasm of lung, unspecified laterality, unspecified part of
lung (HC code)

Order Information

Exam(s): **MR BRAIN W/WO CONTRAST**
Exam Date: [REDACTED]
Ord Provider: [REDACTED]

+4192

Final

EXAMINATION:

MRI Brain without IV contrast
MRI Brain with IV contrast

History: Neoplasm, head, CNS.

COMPARISON STUDIES: [REDACTED] +4119

TECHNIQUE: Multi-planar, multi-sequence brain MRI was performed before and after IV gadolinium.
Contrast: 12 mL of IV MultiHance

FINDINGS:

Paranasal sinuses / mastoid air cells: negative
Calvarium and scalp: negative
White matter: Subtle focus of enhancement high convexity right frontal lobe appears stable. Surrounding T2
hyperintense signal is stable.
Ventricles / sulci / fissures: negative
Masses / hemorrhage / midline shift: negative
Extra-axial spaces: Normal for age.
Enhancement pattern: negative
Vascular structures: negative
Sagittal midline structures: negative
Orbits: negative
Visualized upper neck: negative

[page 18 of 18]
IMPRESSION:

1. Stable left cerebellar resection cavity without evidence of residual or recurrent tumor.
2. Subtle area of enhancement and T2 hyperintense signal high convexity of the right frontal lobe has not significantly changed and remains indeterminate. Continued close interval follow-up is recommended.
3. No evidence of new lesions.

Source: NCI Genomic Data Commons file d28b8c34-a213-4527-a83f-7fe26bb63de1 (ER0385 ER-B0GM Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).